Somatic mutation profile of tumor specimen ALCH-B1L9-TTP1-A (aliquot ALCH-B1L9-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1L9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.2 years (24,559 days).
Specimen ALCH-B1L9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75528852-b0ba-47c6-a4e3-cc52b165ae9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1L9-NB1-A (Blood Derived Normal), aliquot ALCH-B1L9-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/445cc693-e66d-4293-9198-74693480dd94

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 4, Intron 3, In Frame Del 1, 3'UTR 1, Translation Start Site 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIVM-ERCC5 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 162/623 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as rs770246574, COSV63246779; called by muse, mutect2, varscan2
- CBLN2 | c.21del p.P8Hfs*6 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs1270252552; called by mutect2, varscan2
- CSF2RB | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs548203092; called by muse, mutect2
- DLL1 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs754306571; called by muse, mutect2
- ENOX1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 118/431 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1297518858, COSV54905691; called by muse, mutect2, varscan2
- LEMD3 | c.1195A>G p.S399G | Missense Mutation (SNP) | VAF 101/547 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs754287790; called by muse, mutect2, varscan2
- MTHFD1L | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV66210217; called by muse, mutect2, varscan2
- SEPTIN14 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs369566641, COSV101193176; called by muse, mutect2, varscan2
- SLITRK1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV65675004; called by muse, mutect2, varscan2
- SMAD4 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 117/684 reads (17%) | catalogued as COSV61686540, COSV61686776; called by muse, mutect2, varscan2
- SMARCA4 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as COSV60788373; called by muse, mutect2
- TOGARAM2 | c.712C>G p.P238A | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV101091672; called by muse, mutect2, varscan2
- CRB2 | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.344); called by muse, varscan2
- CYLC1 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- DGKI | c.3033C>A p.C1011* | Nonsense Mutation (SNP) | VAF 46/231 reads (20%) | called by muse, mutect2, varscan2
- GPR89B | c.1232C>G p.T411S | Missense Mutation (SNP) | VAF 63/492 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HELB | c.2842A>G p.K948E | Missense Mutation (SNP) | VAF 54/476 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- MUC4 | c.11251T>G p.S3751A | Missense Mutation (SNP) | VAF 96/464 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- NPHP4 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NUP98 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 79/346 reads (23%) | called by muse, mutect2, varscan2
- SEMA3F | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- TAS2R50 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2
- UMPS | c.649_663del p.S217_A221del | In Frame Del (DEL) | VAF 53/421 reads (13%) | called by mutect2, pindel
- ZNF280C | c.576T>A p.S192R | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ZNF808 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ANK3 | c.10236C>T p.I3412= | Silent (SNP) | VAF 42/364 reads (12%) | catalogued as rs762232864; called by muse, mutect2, varscan2
- CYTH4 | c.276C>T p.D92= | Silent (SNP) | VAF 53/285 reads (19%) | catalogued as rs148042663; called by muse, mutect2, varscan2
- F8 | c.5379T>A p.T1793= | Silent (SNP) | VAF 46/482 reads (10%) | called by muse, mutect2
- FBXO24 | c.906C>T p.R302= (on ENST00000241071 / NM_033506.3; = p.R340= on NM_012172.5) | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs142080768; called by muse, mutect2, varscan2
- KAT2B | c.723G>A p.R241= | Silent (SNP) | VAF 18/422 reads (4%) | called by muse, mutect2
- SEPTIN5 | c.870G>T p.T290= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- SPANXN3 | c.264C>T p.G88= | Silent (SNP) | VAF 102/419 reads (24%) | catalogued as rs782242814, COSV100980861, COSV65140598; called by muse, mutect2, varscan2
- TGOLN2 | c.807T>G p.P269= | Silent (SNP) | VAF 40/355 reads (11%) | called by muse, mutect2, varscan2
- TMEM178B | c.567C>T p.G189= | Silent (SNP) | VAF 34/327 reads (10%) | catalogued as rs1244198804; called by muse, mutect2, varscan2
- TNS4 | c.1947C>A p.L649= | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- EPX | c.-35A>G | 5'UTR (SNP) | VAF 36/304 reads (12%) | called by muse, mutect2
- GNG7 | c.-38+16969G>T | Intron (SNP) | VAF 64/284 reads (23%) | called by muse, mutect2, varscan2
- HSPG2 | c.575-635C>T | Intron (SNP) | VAF 10/57 reads (18%) | catalogued as rs1434921453, COSV65930289; called by mutect2, varscan2
- MROH8 | c.109+2788C>G | Intron (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- TMEM135 | c.*1075C>T | 3'UTR (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
